Somatic mutation profile of tumor specimen C3N-03889-02 (aliquot CPT0222360006) from CPTAC case C3N-03889, project CPTAC-3 (Gum — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.4 years (19,505 days).
Specimen C3N-03889-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Alveolar Ridge; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be214eb3-1eee-4bc9-bb61-cd5a51b27c7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03889-71 (Blood Derived Normal), aliquot CPT0222470002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a054592a-a810-49d7-b0a6-a47c63111aef

The open-access MAF lists 109 somatic variants for this specimen: 78 protein-altering or splice-affecting, 19 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 19, Nonsense Mutation 7, Intron 6, 3'UTR 3, Splice Region 2, 3'Flank 2, Frame Shift Ins 2, Frame Shift Del 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAM19 | c.1648A>G p.T550A | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as COSV57429762; called by muse, mutect2, varscan2
- CDC42BPA | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs772856713, COSV62020082; called by muse, mutect2, varscan2
- CFAP46 | c.3791C>T p.T1264M | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs533730270, COSV63949557; called by muse, mutect2, varscan2
- CGNL1 | c.2073G>T p.M691I | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55565714; called by muse, mutect2, varscan2
- COL2A1 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 121/772 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs778135776, CD1513906, COSV61534954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRACD | c.2987C>T p.P996L | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs1440497582; called by muse, mutect2
- CRYGC | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 84/422 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs1469741282, COSV56408965; called by muse, mutect2, varscan2
- DNAAF2 | c.2327C>T p.T776I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs748119712; called by muse, mutect2, varscan2
- EFL1 | c.1883G>A p.S628N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV51608319; called by muse, mutect2
- ENAH | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1190159446, COSV52866610, COSV52873142; called by muse, mutect2, varscan2
- EPS8L1 | c.479C>T p.S160L (on ENST00000201647 / NM_133180.3; = p.S33L on NM_017729.3) | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.697); catalogued as rs772471747, COSV52382109; called by muse, mutect2, varscan2
- GRM8 | c.1004G>T p.R335L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV58834027; called by muse, mutect2
- IFT122 | c.2413C>T p.R805C (on ENST00000348417 / NM_052989.3; = p.R746C on NM_018262.4) | Missense Mutation (SNP) | VAF 74/521 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1413221093, COSV56205944; called by muse, mutect2, varscan2
- KANSL1 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 29/227 reads (13%) | catalogued as COSV52267578; called by muse, mutect2, varscan2
- KIF26A | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 50/333 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs1194841995; called by muse, mutect2, varscan2
- KMT2C | c.4174C>G p.Q1392E | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV51426883; called by muse, mutect2
- LRRC27 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.07); catalogued as rs778575373; called by muse, mutect2, varscan2
- MSR1 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs780725414; called by muse, mutect2, varscan2
- MYO5C | c.2599C>T p.R867W | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766392804, COSV55911278; called by muse, mutect2, varscan2
- NOTCH1 | c.4460G>A p.W1487* | Nonsense Mutation (SNP) | VAF 208/693 reads (30%) | catalogued as COSV53031807; called by muse, mutect2, varscan2
- NR4A3 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs1339423299, COSV58246924; called by muse, mutect2, varscan2
- OR1L1 | c.41A>T p.N14I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs538789690; called by muse, mutect2, varscan2
- PARP8 | c.2117C>G p.S706C | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs112678068; called by muse, mutect2, varscan2
- PDGFRA | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 76/563 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57271399, COSV57277919; called by muse, mutect2, varscan2
- PEX5 | c.318C>T p.A106= | Splice Region (SNP) | VAF 95/701 reads (14%) | catalogued as rs149185061; ClinVar: likely benign; called by muse, mutect2, varscan2
- PIAS1 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 65/434 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs778533264; called by muse, mutect2, varscan2
- PRAMEF4 | c.1104A>C p.Q368H | Missense Mutation (SNP) | VAF 184/1190 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs369619869; called by muse, varscan2
- PRPF31 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 153/918 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs201906830, COSV58087372; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REX1BD | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 29/261 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs549198470; called by muse, mutect2, varscan2
- RFLNA | c.493C>T p.R165C (on ENST00000546355 / NM_001365156.1; = p.R84C on NM_181709.4) | Missense Mutation (SNP) | VAF 127/767 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs150991901; called by muse, mutect2, varscan2
- SBNO1 | c.941G>A p.R314H (on ENST00000420886; = p.R313H on NM_018183.5) | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375723737; called by muse, mutect2, varscan2
- SCN1A | c.4486C>T p.Q1496* (on ENST00000303395 / NM_001202435.3; = p.Q1485* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | catalogued as rs1553521559, CD068492; called by muse, mutect2, varscan2
- SH3GL1 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 68/452 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs563998650; called by muse, mutect2, varscan2
- SHANK3 | c.3859G>A p.D1287N | Missense Mutation (SNP) | VAF 145/913 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1167545316; called by muse, mutect2, varscan2
- SP140 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs201286206; called by muse, mutect2, varscan2
- SPATA31D1 | c.2792C>T p.S931L | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776159891, COSV61195645; called by muse, varscan2
- TMEM52 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 107/649 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs748662303, COSV100205549; called by muse, mutect2, varscan2
- TSPY1 | c.364G>T p.V122F | Missense Mutation (SNP) | VAF 102/674 reads (15%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.983); catalogued as rs1240362123; called by mutect2, varscan2
- TTN | c.66088G>A p.D22030N (on ENST00000591111; = p.D14606N on NM_003319.4) | Missense Mutation (SNP) | VAF 24/129 reads (19%) | PolyPhen probably damaging (0.943); catalogued as rs774191400; called by muse, mutect2, varscan2
- TTN | c.62395G>A p.G20799S (on ENST00000591111; = p.G13375S on NM_003319.4) | Missense Mutation (SNP) | VAF 61/444 reads (14%) | PolyPhen benign (0.246); catalogued as rs727503576; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WBP11 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53761795; called by muse, mutect2, varscan2
- ZNF224 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as COSV100425606; called by muse, mutect2, varscan2
- ZNF23 | c.1375G>A p.V459I | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.873); catalogued as rs1330784737; called by muse, mutect2, varscan2
- BEGAIN | c.1326C>A p.C442* | Nonsense Mutation (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- CELSR3 | c.4313T>C p.L1438P | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- CTH | c.648C>G p.G216= | Splice Region (SNP) | VAF 27/206 reads (13%) | called by muse, mutect2, varscan2
- DDC | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 96/677 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- DERPC | c.834_843delinsG p.I278_A281delinsM | In Frame Del (DEL) | VAF 20/129 reads (16%) | called by pindel, varscan2*
- DIP2C | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- DMRT2 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- FAM124A | c.1387G>A p.G463R (on ENST00000322475 / NM_001242312.2; = p.G499R on NM_145019.4) | Missense Mutation (SNP) | VAF 78/404 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM83E | c.91_92dup p.Q31Hfs*10 | Frame Shift Ins (INS) | VAF 54/455 reads (12%) | called by mutect2, pindel, varscan2
- GLI3 | c.3944A>G p.Q1315R | Missense Mutation (SNP) | VAF 74/415 reads (18%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRF8 | c.1263C>A p.N421K | Missense Mutation (SNP) | VAF 96/739 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- IRX1 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- KDF1 | c.687_697del p.M229Ifs*8 | Frame Shift Del (DEL) | VAF 60/403 reads (15%) | called by mutect2, pindel
- KDM3B | c.2761C>T p.R921W | Missense Mutation (SNP) | VAF 79/533 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- KIF13B | c.3629A>G p.E1210G | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- LAMA3 | c.6784A>T p.I2262L (on ENST00000313654 / NM_198129.4; = p.I653L on NM_000227.6) | Missense Mutation (SNP) | VAF 79/553 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MDN1 | c.593A>T p.N198I | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2
- MORC3 | c.2418A>T p.K806N | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- NCOR1 | c.6832A>C p.K2278Q | Missense Mutation (SNP) | VAF 61/472 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PC | c.1266C>G p.Y422* | Nonsense Mutation (SNP) | VAF 78/540 reads (14%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.1657C>A p.L553M | Missense Mutation (SNP) | VAF 23/667 reads (3%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.72); called by muse, mutect2
- PIK3R2 | c.1762C>A p.Q588K | Missense Mutation (SNP) | VAF 50/393 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- RBBP8 | c.1561C>T p.L521F | Missense Mutation (SNP) | VAF 61/399 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- SIGLEC10 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 81/597 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SLC18B1 | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 23/241 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SLITRK2 | c.570dup p.N191Efs*2 | Frame Shift Ins (INS) | VAF 39/139 reads (28%) | called by mutect2, pindel, varscan2
- SPHKAP | c.3427G>T p.G1143* | Nonsense Mutation (SNP) | VAF 27/239 reads (11%) | called by muse, mutect2, varscan2
- ST18 | c.2020A>G p.K674E | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYK | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TANC1 | c.1164G>C p.R388S | Missense Mutation (SNP) | VAF 50/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TECTA | c.5493G>T p.R1831S | Missense Mutation (SNP) | VAF 89/564 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM43 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 113/646 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- UBTF | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP7 | c.1259A>G p.K420R | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM30 | c.348G>A p.V116= | Silent (SNP) | VAF 58/299 reads (19%) | called by muse, mutect2, varscan2
- ADRA2C | c.87C>T p.G29= | Silent (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- DEF6 | c.378C>T p.N126= | Silent (SNP) | VAF 63/410 reads (15%) | called by muse, mutect2, varscan2
- FBXL8 | c.972G>A p.A324= | Silent (SNP) | VAF 92/480 reads (19%) | called by muse, mutect2, varscan2
- INHA | c.285C>T p.D95= | Silent (SNP) | VAF 51/331 reads (15%) | called by muse, mutect2, varscan2
- KIF27 | c.4029T>A p.V1343= | Silent (SNP) | VAF 37/207 reads (18%) | called by muse, mutect2, varscan2
- KRT16 | c.856C>T p.L286= | Silent (SNP) | VAF 152/987 reads (15%) | called by muse, mutect2, varscan2
- MACROH2A2 | c.312C>T p.G104= | Silent (SNP) | VAF 45/292 reads (15%) | catalogued as rs1411797092; called by muse, mutect2, varscan2
- MDN1 | c.207T>G p.L69= | Silent (SNP) | VAF 112/699 reads (16%) | called by muse, mutect2, varscan2
- NCR3LG1 | c.312C>T p.D104= | Silent (SNP) | VAF 49/362 reads (14%) | catalogued as rs78000302, COSV59070118; called by muse, mutect2, varscan2
- NRXN1 | c.333C>T p.D111= | Silent (SNP) | VAF 52/257 reads (20%) | catalogued as rs1447163289, COSV101276275, COSV68015915; called by muse, mutect2, varscan2
- POT1 | c.1269C>A p.I423= | Silent (SNP) | VAF 23/154 reads (15%) | called by muse, mutect2, varscan2
- PREX1 | c.3744C>A p.T1248= | Silent (SNP) | VAF 70/450 reads (16%) | catalogued as rs1398033736; called by muse, mutect2, varscan2
- PRKCZ | c.432C>T p.C144= | Silent (SNP) | VAF 37/216 reads (17%) | catalogued as rs569792186; called by muse, mutect2, varscan2
- RCOR2 | c.1225T>C p.L409= | Silent (SNP) | VAF 42/263 reads (16%) | catalogued as rs777308760; called by muse, mutect2, varscan2
- TRPM1 | c.2028C>T p.F676= | Silent (SNP) | VAF 72/402 reads (18%) | catalogued as rs376395058, COSV56631656, COSV99855141; called by muse, mutect2, varscan2
- UBASH3B | c.66C>T p.V22= | Silent (SNP) | VAF 42/278 reads (15%) | called by muse, mutect2, varscan2
- WNK1 | c.402C>T p.A134= | Silent (SNP) | VAF 56/339 reads (17%) | catalogued as rs201360097; called by muse, mutect2, varscan2
- ZAR1 | c.129C>T p.R43= | Silent (SNP) | VAF 43/223 reads (19%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+38570G>A | Intron (SNP) | VAF 48/354 reads (14%) | catalogued as rs771559008; called by muse, mutect2, varscan2
- CLTCL1 | c.-12C>T | 5'UTR (SNP) | VAF 15/114 reads (13%) | catalogued as rs1555994036; called by muse, mutect2, varscan2
- DNAJC17 | c.*22C>T | 3'UTR (SNP) | VAF 37/266 reads (14%) | called by muse, mutect2, varscan2
- DOP1B | c.5315+11C>T | Intron (SNP) | VAF 28/165 reads (17%) | catalogued as rs547578593; called by muse, mutect2, varscan2
- EYS | c.1767-6781C>T | Intron (SNP) | VAF 91/635 reads (14%) | catalogued as rs776098671; called by muse, mutect2, varscan2
- F2 | c.423-22G>A | Intron (SNP) | VAF 120/632 reads (19%) | called by muse, mutect2, varscan2
- HDAC4 | c.*10G>A | 3'UTR (SNP) | VAF 49/315 reads (16%) | catalogued as rs759354378; called by muse, mutect2, varscan2
- IGFN1 | c.1242-997G>T | Intron (SNP) | VAF 52/350 reads (15%) | called by muse, mutect2, varscan2
- LINC01630 | n.219+73312G>C | Intron (SNP) | VAF 54/440 reads (12%) | called by muse, mutect2, varscan2
- PKMYT1 | chr16:2972702 G>T | 3'Flank (SNP) | VAF 62/383 reads (16%) | called by muse, mutect2, varscan2
- RGS21 | c.*5G>A | 3'UTR (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- VPS26C | chr21:37221391 C>G | 3'Flank (SNP) | VAF 107/642 reads (17%) | called by muse, mutect2, varscan2
